Somatic mutation profile of tumor specimen TCGA-12-5299-01A (aliquot TCGA-12-5299-01A-02D-1486-08) from TCGA case TCGA-12-5299, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.0 years (20,463 days).
Specimen TCGA-12-5299-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7bd3be0-f0eb-4027-b855-11d261e1393e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-5299-10A (Blood Derived Normal), aliquot TCGA-12-5299-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35275073-7f36-49eb-876d-8fcf581378d7

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Nonsense Mutation 2, 5'Flank 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD8 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV55541974; called by muse, mutect2, varscan2
- AIRE | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 75/132 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs370599883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASKIN2 | c.2291C>G p.S764C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV58598747; called by muse, mutect2, varscan2
- CXorf58 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 99/236 reads (42%) | catalogued as rs771619651, COSV64858189; called by muse, mutect2, varscan2
- DGKE | c.1582G>T p.G528W | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV52350882; called by muse, mutect2
- DNAH8 | c.5867G>A p.R1956H | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139579198, COSV59427962; called by muse, mutect2, varscan2
- EIF4E1B | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.334); catalogued as COSV53781476; called by muse, mutect2, varscan2
- FAM131C | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs771345920, COSV65153993; called by muse, mutect2, varscan2
- GRIK3 | c.1784A>G p.H595R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66144401; called by muse, mutect2, varscan2
- ITGAX | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs200320669, COSV51649582; called by muse, mutect2, varscan2
- ITPR1 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56996602; called by mutect2, varscan2
- KCNT1 | c.3014G>A p.R1005H (on ENST00000488444; = p.R1024H on NM_020822.3) | Missense Mutation (SNP) | VAF 250/366 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs765283220, COSV53702453; called by muse, mutect2, varscan2
- KRT23 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as rs148371500, COSV52928710; called by muse, mutect2, varscan2
- KSR2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 162/365 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs889506320, COSV100348747, COSV60385356; called by muse, mutect2, varscan2
- MEGF8 | c.2965G>A p.G989S (on ENST00000251268 / NM_001271938.2; = p.G922S on NM_001410.3) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs539307956, COSV52096170; called by muse, mutect2, varscan2
- NID1 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 156/378 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs147220938, COSV51620798; called by muse, mutect2, varscan2
- PCDHGB2 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); catalogued as COSV54002833; called by muse, mutect2, varscan2
- POU2F3 | c.133-1G>C p.X45_splice | Splice Site (SNP) | VAF 346/763 reads (45%) | catalogued as COSV52796488; called by muse, mutect2, varscan2
- PTPRD | c.2432G>A p.R811H | Missense Mutation (SNP) | VAF 200/229 reads (87%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as rs544419494, COSV61971683; called by muse, mutect2, varscan2
- RCAN3 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 46/127 reads (36%) | catalogued as rs535171467, COSV65558297; called by muse, mutect2, varscan2
- SLC44A5 | c.1904G>C p.R635T | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV63771068; called by muse, mutect2, varscan2
- SYCP2 | c.877-7_877-3del | Splice Region (DEL) | VAF 22/68 reads (32%) | catalogued as rs1192782267; called by pindel, varscan2
- TMEM117 | c.1517C>T p.T506M | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.043); catalogued as rs150984405; called by muse, mutect2, varscan2
- ZNF513 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 195/434 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs371898387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKAR | c.3696G>A p.L1232= | Silent (SNP) | VAF 66/152 reads (43%) | catalogued as COSV55616153; called by muse, mutect2, varscan2
- ARSD | c.705C>T p.G235= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs758857063, COSV54202051; called by muse, mutect2, varscan2
- KCNH2 | c.1524C>T p.F508= | Silent (SNP) | VAF 46/185 reads (25%) | catalogued as rs555601424, COSV51132408, COSV51209028; called by muse, mutect2
- PCDHA3 | c.1014C>T p.L338= | Silent (SNP) | VAF 111/251 reads (44%) | catalogued as COSV63543629; called by muse, mutect2, varscan2
- RHBDD2 | c.1035G>T p.G345= | Silent (SNP) | VAF 147/578 reads (25%) | catalogued as COSV50087961; called by muse, mutect2, varscan2
- SDK1 | c.3132C>T p.D1044= | Silent (SNP) | VAF 44/213 reads (21%) | catalogued as rs775327604, COSV67360188; called by muse, varscan2
- SLC17A2 | c.813A>T p.T271= | Silent (SNP) | VAF 64/157 reads (41%) | catalogued as COSV55354181; called by muse, mutect2, varscan2
- TMPRSS4 | c.1038G>A p.A346= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs764161015, COSV71109553; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848792 A>T | 5'Flank (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- MFRP | chr11:119345564 G>C | 5'Flank (SNP) | VAF 53/127 reads (42%) | catalogued as rs200251814, COSV64129009; called by muse, mutect2, varscan2
